Gene-level copy-number profile of tumor specimen TCGA-49-4488-01A from TCGA case TCGA-49-4488, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 74.8 years (27,332 days).
Specimen TCGA-49-4488-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.cff4085b-afd7-48f6-8111-92781cff4c80.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-4488-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a39eb1b8-5981-45f0-b685-04cdeaae63ea

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,316; copy number 2: 11,115; copy number 3: 21,309; copy number 4: 14,484; copy number 5: 4,198; copy number 6: 4,519; copy number 7: 871; copy number 8: 259; copy number 9: 375; copy number 10: 141; copy number 12: 164; copy number 14: 10; copy number 15: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-4488-01A-01D-1752-01): tumor purity 0.45, ploidy 4.96, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,810 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,161,387–43,456,995, 115 genes, copy number 12 (within-gene range 3–12) (broad region; genes not listed).
- chr1:56,929,207–59,876,322, 34 genes, copy number 10: C8B, AL161740.1, DAB1, AL390243.1, RPS20P5, DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1.
- chr1:87,620,803–93,554,661, 117 genes, copy number 10–12 (broad region; genes not listed).
- chr1:93,592,199–93,605,573, 1 gene, copy number 12: BCAR3-AS1.
- chr1:246,516,039–247,393,839, 42 genes, copy number 8: LINC01743, AL356583.3, AL356583.2, TFB2M, CNST, AL591623.1, AL591623.2, AL591848.2, AL591848.1, SCCPDH, RPL35AP6, KIF28P, AL591848.3, LINC01341, AC113174.1, AC113174.2, AHCTF1, ZNF695, ZNF670-ZNF695, AL512637.2, ZNF670, AL512637.1, AL627095.1, ZNF669, AL627095.2, C1orf229, FGFR3P6, ZNF124, AL390728.3, AL390728.2, AL390728.6, AL390728.4, MIR3916, RNA5SP82, AL390728.5, AL390728.1, VN1R17P, VN1R5, Y_RNA, ZNF496, AC104335.1, AC104335.2.
- chr2:52,474,073–54,383,742, 25 genes, copy number 7: GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3, AC069157.2, AC069157.1, ASB3, RNU6-997P, CHAC2, ERLEC1, MIR3682, GPR75, PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73.
- chr2:54,516,048–54,540,697, 2 genes, copy number 7 (within-gene range 6–7): SPTBN1-AS1, RPL23AP32.
- chr2:94,867,486–94,947,341, 1 gene, copy number 9 (within-gene range 4–9): AC097374.1.
- chr2:94,899,566–100,996,829, 174 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr3:5,250,177–6,365,885, 6 genes, copy number 8: MIR4790, RN7SL553P, AC026202.1, AC087857.1, AC026167.1, AC027119.1.
- chr3:9,600,748–11,263,557, 59 genes, copy number 7–10: DUSP5P2, MTMR14, AC022382.2, CPNE9, BRPF1, OGG1, CAMK1, TADA3, ARPC4, ARPC4-TTLL3, TTLL3, AC022382.1, RPUSD3, CIDEC, JAGN1, IL17RE, IL17RC, RNU6-882P, AC018809.3, CRELD1, AC018809.1, PRRT3, PRRT3-AS1, AC018809.2, EMC3, EMC3-AS1, CYCSP10, AC022007.1, CIDECP1, FANCD2, RNU6-670P, CYCSP11, FANCD2OS, BRK1, VHL, AC034193.1, IRAK2, TATDN2, AC022384.1, LINC00852, GHRL, GHRLOS, AC022384.2, SEC13, ATP2B2, MIR378B, MIR885, ATP2B2-IT1, ATP2B2-IT2, LINC00606, AC018495.1, SLC6A11, AC027128.1, SLC6A1, SLC6A1-AS1, AC066580.1, HRH1, AC083855.2, CHCHD4P4.
- chr3:11,290,406–11,290,663, 1 gene, copy number 7: AC083855.1.
- chr5:58,198–5,490,220, 117 genes, copy number 8 (broad region; genes not listed).
- chr5:6,019,029–9,045,940, 68 genes, copy number 9 (broad region; genes not listed).
- chr5:9,053,816–9,053,895, 1 gene, copy number 9: MIR4636.
- chr7:38,239,580–38,656,613, 27 genes, copy number 8: TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1, AMPH, RN7SL83P, KRT8P20.
- chr8:46,028,804–46,028,892, 1 gene, copy number 10: AC118650.1.
- chr8:112,222,928–113,436,939, 1 gene, copy number 7 (within-gene range 6–7): CSMD3.
- chr8:112,538,889–145,066,685, 517 genes, copy number 7 (broad region; genes not listed).
- chr12:19,724,435–20,136,163, 6 genes, copy number 8: RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468.
- chr12:68,805,011–68,971,570, 9 genes, copy number 7: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr14:18,333,726–20,357,904, 113 genes, copy number 7 (broad region; genes not listed).
- chr14:24,809,656–25,050,297, 1 gene, copy number 7 (within-gene range 5–7): STXBP6.
- chr14:25,124,467–28,490,362, 24 genes, copy number 7: LINC02286, HMGN2P6, OR7K1P, AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3.
- chr14:28,936,889–29,372,406, 1 gene, copy number 9 (within-gene range 6–9): AL135878.1.
- chr14:29,210,986–42,268,586, 199 genes, copy number 7–9 (broad region; genes not listed).
- chr16:26,302,064–29,698,699, 127 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr22:33,922,422–35,394,214, 21 genes, copy number 8: Z73429.1, LINC01643, Z68323.1, AL021877.1, AL021877.2, Z82196.1, Z82196.2, LINC02885, ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, Z82244.2, Z82244.1, HMOX1.

Autosomal genes at a single copy (total copy number 1): 2,316. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
